Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3527, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3527-01A (Primary Tumor).

*** Diagnosis / Diagnoses: ***

Right hemicolectomy specimen with an ulcerated cecum carcinoma conforming to the histological type of a moderately differentiated colorectal adenocarcinoma, affecting Bauhin's valve and with a greatest diameter of 4.5 cm. Invasive spread of tumor within all layers of the intestinal wall and as far as the neighboring mesocolic fatty tissue and the subserosa. Remainder of colon mucosal membrane with a hyperplastic polyp.

Appendix with apparent post-inflammatory fibrosis of the wall.

Oral and aboral resection margins and large omentum tumor-free.

Fifteen mesocolic and mesenteric lymph nodes tumor-free with uncharacteristic reactive changes.

Tumor stage thus pT3 pN0 (0/15) L0, V0; G2

Source: NCI Genomic Data Commons file 959cba98-1958-4264-97d8-d754c60b48a7 (TCGA-AA-3527.401E54D1-5D40-4533-8F5A-939ED4107655.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).